Gene-level copy-number profile of tumor specimen HTMCP-01-07-00336-01A from CGCI case HTMCP-01-07-00336, project CGCI-HTMCP-DLBCL (HIV+ Tumor Molecular Characterization Project - Diffuse Large B-Cell Lymphoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Diffuse large B-cell lymphoma, NOS; Tissue or organ of origin: Hematopoietic system, NOS; Age at diagnosis: 34.2 years (12,508 days).
Specimen HTMCP-01-07-00336-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file fad2fd49-1398-4483-9973-a6c160113f42.wgs.ASCAT.gene_level.copy_number_variation.tsv, workflow AscatNGS on whole-genome sequencing of the tumor/normal pair, germline comparator HTMCP-01-07-00336-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 1,740 have no estimate.
https://portal.gdc.cancer.gov/files/7a44079f-2758-4812-a047-59d7019a0115

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 0: 51; copy number 1: 2,765; copy number 2: 55,552; copy number 3: 271; copy number 4: 108; copy number 5: 36; copy number 6: 14; copy number 7: 51; copy number 8: 7; copy number 9: 12; copy number 10: 1; copy number 11: 1; copy number 14: 1; copy number 15: 1; copy number 23: 8; copy number 26: 1; copy number 38: 1; copy number 52: 2.

Homozygous deletions (total copy number 0; autosomes only): 3 genes in 2 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:46,891,639–46,892,830, 1 gene (within-gene range 0–2): TUBAP8.
- chr16:32,877,469–32,888,874, 2 genes: SLC6A10P, AC142086.1.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 134 genes in 31 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr2:62,533,681–62,662,829, 1 gene, copy number 6 (within-gene range 2–6): AC092155.1.
- chr2:132,147,591–132,257,969, 1 gene, copy number 7 (within-gene range 3–7): ANKRD30BL.
- chr2:132,253,154–132,257,080, 2 genes, copy number 7: RNA5-8SP5, MIR663B.
- chr3:90,261,414–90,261,708, 1 gene, copy number 8: HSPE1P19.
- chr5:43,444,252–43,483,893, 1 gene, copy number 6: TMEM267.
- chr5:98,025,965–98,026,139, 1 gene, copy number 11: AC008834.1.
- chr5:177,782,197–177,794,396, 1 gene, copy number 9 (within-gene range 2–9): AC140125.2.
- chr6:30,720,352–30,725,426, 2 genes, copy number 8: TUBB, AL662797.1.
- chr6:32,517,353–32,530,287, 1 gene, copy number 10: HLA-DRB5.
- chr7:38,239,580–38,249,572, 1 gene, copy number 5: TRGC2.
- chr7:38,257,879–38,340,998, 13 genes, copy number 5 (within-gene range 2–5): TRGC1, TRGJ1, TRGJP, TRGV11, TRGVB, TRGV10, AC006033.1, TRGV9, TRGVA, AC006033.2, TRGV8, TRGV7, TRGV6.
- chr7:62,275,361–62,275,678, 1 gene, copy number 7: AC128676.1.
- chr7:75,391,955–75,416,787, 3 genes, copy number 26–52 (within-gene range 2–52): AC211486.1, TRIM73, NSUN5P1.
- chr7:150,512,559–150,604,644, 5 genes, copy number 5: STRADBP1, GIMAP7, ALDH7A1P3, GIMAP4, AC069304.3.
- chr8:7,926,337–7,977,985, 5 genes, copy number 6: ZNF705B, DEFB108A, AC130365.1, USP17L8, USP17L3.
- chr9:40,883,634–40,929,092, 2 genes, copy number 9: AL353626.2, MIR1299.
- chr10:95,141,925–95,168,425, 1 gene, copy number 14: AL157834.4.
- chr11:48,880,111–48,908,946, 4 genes, copy number 8: AC027369.6, AC027369.3, AC027369.4, AC027369.5.
- chr11:54,706,832–54,725,816, 2 genes, copy number 6: OR4A5, OR4A6P.
- chr11:63,137,867–63,369,718, 1 gene, copy number 5 (within-gene range 2–5): SLC22A10.
- chr11:63,237,957–63,410,294, 4 genes, copy number 5: AP001880.2, CCND2P1, AP001880.1, SLC22A9.
- chr14:18,333,726–18,341,859, 1 gene, copy number 38: CR383658.1.
- chr14:22,147,995–22,490,553, 44 genes, copy number 7: TRAV27, TRAV28, TRAV29DV5, TRAV30, TRAV31, TRAV32, TRAV33, AC244502.1, TRAV26-2, TRAV34, TRAV35, TRAV36DV7, TRAV37, TRAV38-1, TRAV38-2DV8, TRAV39, TRAV40, TRAV41, AC244502.2, AC244502.3, TRDV2, TRDD1, TRDD2, TRDD3, TRDJ1, TRDJ4, TRDJ2, TRDJ3, TRDC, TRDV3, TRAJ61, TRAJ60, TRAJ59, TRAJ58, TRAJ57, TRAJ56, TRAJ55, TRAJ54, TRAJ53, TRAJ52, TRAJ51, TRAJ50, TRAJ49, TRAJ48.
- chr14:22,547,506–22,552,156, 1 gene, copy number 7: TRAC.
- chr16:32,388,135–32,436,203, 1 gene, copy number 5: AC138915.2.
- chr16:32,475,051–32,478,250, 1 gene, copy number 9: ABCD1P3.
- chr16:32,715,931–32,873,128, 12 genes, copy number 5–23: AC138907.6, ABHD17AP7, AC138907.2, AC138907.4, HERC2P5, AC138907.8, AC138907.9, AC138907.10, AC137761.1, AC137761.2, AC142086.2, BCAP31P2.
- chr16:34,013,394–34,051,363, 3 genes, copy number 6: AC133561.2, AC133561.4, AC133561.3.
- chr16:34,266,041–35,104,834, 10 genes, copy number 5–6: BCLAF1P2, AC135776.4, LINC02184, AC135776.1, AC135776.2, AC135776.3, CCNYL3, CLUHP11, NAMPTP3, VPS35P1.
- chr22:15,528,192–15,578,006, 6 genes, copy number 9: OR11H1, AP000534.2, ARHGAP42P3, AP000534.1, AP000533.2, AP000533.1.
- chr22:15,852,990–15,893,942, 2 genes, copy number 7: NBEAP3, TOMM40P2.

Autosomal genes at a single copy (total copy number 1): 87. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
